Somatic mutation profile of tumor specimen TCGA-KL-8332-01A (aliquot TCGA-KL-8332-01A-11D-2310-10) from TCGA case TCGA-KL-8332, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 55.1 years (20,128 days).
Specimen TCGA-KL-8332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af6efc00-4806-4bfc-8883-0bd1d25bae7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8332-11A (Solid Tissue Normal), aliquot TCGA-KL-8332-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b471b1d-f16c-4b17-9572-f945a69f3cbc

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Ins 3, Silent 3, Frame Shift Del 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA0408 | c.381dup p.S128Ifs*18 | Frame Shift Ins (INS) | VAF 26/111 reads (23%) | catalogued as rs762399944; called by mutect2, varscan2
- PECR | c.65T>G p.I22S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99526846; called by muse, mutect2
- PLCB1 | c.3395G>A p.R1132H | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs765705013, COSV62062174; called by muse, mutect2, varscan2
- TNS2 | c.723C>G p.I241M (on ENST00000314250 / NM_170754.4; = p.I251M on NM_015319.2) | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs749495661, COSV58578530; called by muse, mutect2, varscan2
- VARS2 | c.1731G>C p.E577D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100422979; called by muse, mutect2
- GOLGA4 | c.1414A>T p.K472* | Nonsense Mutation (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- HDAC7 | c.924del p.I309Ffs*14 (on ENST00000427332; = p.I348Ffs*14 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- HSPG2 | c.7255T>A p.S2419T | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LARP7 | c.63dup p.E22Rfs*3 | Frame Shift Ins (INS) | VAF 39/112 reads (35%) | called by mutect2, pindel, varscan2
- PNMA5 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.4574del p.G1525Efs*37 | Frame Shift Del (DEL) | VAF 98/313 reads (31%) | called by mutect2, pindel, varscan2
- RMDN2 | c.986C>T p.T329I (on ENST00000354545 / NM_001322212.2; = p.T507I on NM_144713.5) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2
- SLC9A1 | c.937_938insT p.G313Vfs*166 | Frame Shift Ins (INS) | VAF 22/44 reads (50%) | called by mutect2, varscan2
- UROC1 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY7 | c.3045T>A p.T1015= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV54264406; called by muse, mutect2, varscan2
- BPIFC | c.840T>A p.I280= | Silent (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- FAM168B | c.183G>A p.V61= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs1026024311; called by muse, mutect2, varscan2
- RBMXL2 | c.*223G>A | 3'UTR (SNP) | VAF 51/160 reads (32%) | catalogued as COSV100182338; called by muse, mutect2, varscan2
